CGCI case HTMCP-01-15-00366 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/effc3f90-0882-4352-8948-8f1b483dfa0b

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 46 years; Vital status: Dead; Days to death: 871 days (2.4 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 46.8 years (17,110 days); Year of diagnosis: 2017; Method of diagnosis: Biopsy; Ann Arbor clinical stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 871 days (2.4 years); Max tumor bulk site: Other.
   Pathology details: Lymph node involved site: Inguinal.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Femoral; Tumor largest dimension diameter: 2.2 cm.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (3 entries)
- Days to follow up: 429 days (1.2 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 429 days (1.2 years).
- Days to follow up: 871 days (2.4 years); Disease response: With Tumor.
- Follow-up contacts recording only the day: day -1,566, day 0, day 163, day 563.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD138 (IHC): Negative.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD30 (IHC): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Positive; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 1197 [Blood test normal range upper: 210].

Other clinical attributes
- Day -1,566: Risk factors: HIV/AIDS.
- Day -1,566: Comorbidities: HIV/AIDS.
- Day 0: Weight: 63.4 kg; Height: 162.56 cm; BMI: 24; CD4 count: 168; Haart treatment indicator: Yes; HIV viral load: 7214.
- Day 0: Comorbidities: Human Papillomavirus Infection.
- Day 0: AIDS risk factors: Pneumocystis Pneumonia.
- Day 0: Risk factors: Hepatitis B Infection.
- Day 0: Comorbidities: Hepatitis B Infection.
- Day 163: Nadir CD4 count: 39.

Biospecimens (3 samples)
- Sample HTMCP-01-15-00366-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-15-00366-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-15-00366-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lost to follow-up: No.
- History of disease: Year of HIV diagnosis: 2012; Prior aids conditions: Pneumocystis jirovecii pneumonia; Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes; History relevant infectious diagnosis: Hepatitis B and Trichomoniasis.
- Primary pathology: Method initial path diagnosis: Biopsy (all types).
- Tests performed: LDH level: 1197; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD138; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: CD79a; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: CD30; Immunophenotypic analysis method: Immunohistochemistry.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes.
- Follow-up form 1, New tumor event: New tumor event type: Distant Metastasis; New tumor event site: Lymph Node(s); New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2: Treatment outcome first course: Complete Remission/Response; Cause of death: Non-Cancer Related; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-15-00366-01A-01E-11051:
- % tumour top: 70
- % tumour bottom: 75

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-15-00366-01A-01S-11051:
- % tumour top: 70
- % tumour bottom: 75
